Surgical pathology report (de-identified scan), TCGA case TCGA-26-5135, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-5135-01A (Primary Tumor).

TCGA-26-5135

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

A. Brain tumor (S) A. Frozen Section Charge (S)

CLINICAL HISTORY: here for left craniotomy for tumor.

GROSS DESCRIPTION: Received the following specimen(s) in the Department of Pathology, labeled with the patient's name and hospital #:

A. Brain tumor

A. The specimen is received fresh, designated "brain tumor," and consists of a 1.2 x 1.3 x 1.0 cm aggregate of tan to beige soft tissue pieces. A representative portion is submitted for frozen section. Frozen section diagnosis is, "malignant glioma," by . The frozen section tissue is submitted in cassette FSA1. A portion of the remaining tissue is submitted for and the remaining tissue is submitted in cassette A2.

DIAGNOSIS:

A. "Brain tumor:"

Glioblastoma multiforme (WHO Grade IV astrocytoma)

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist:

Note: Test systems have been developed and their performance characteristics determined by . Some tests have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of as qualified to perform high complexity clinical laboratory testing.

Electronically signed

Source: NCI Genomic Data Commons file be737d7e-5a1f-490e-b3f5-86d1cf4e0b88 (TCGA-26-5135.89A229AB-908A-4062-9CE6-16BCA172FA02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).